Surgical pathology report (de-identified scan), TCGA case TCGA-EM-A2P3, project TCGA-THCA (Thyroid Carcinoma), tissue source site University Health Network, specimen TCGA-EM-A2P3-01A (Primary Tumor).

[page 1 of 2]
LABORATORY MEDICINE PROGRAM

Surgical Pathology Consultation Report

Patient

Name:

MRN:

DOB:

Gender: F

HCN:

Ordering

MD:

Copy To:

Service:

Visit #:

Location:

Facility:

Accession #:

Collected:

Received:

Reported:

Specimen(s) Received

1. Thyroid: right hemi-thyroid lobe- stitch marks superior pole

Diagnosis

Multifocal papillary carcinoma, dominant 1.4 cm, mixed classical and follicular variant, right; mild follicular nodular disease:

Thyroid, right hemithyroidectomy specimen. See Comment.

Synoptic Data

Procedure: Right hemithyroidectomy
Received: Fresh
Specimen Integrity: Intact
Specimen Size: Right lobe:
4.1 cm
2.0 cm
1.3 cm
Isthmus +/- pyramidal lobe:
1.9 cm
0.3 cm
0.2 cm
Specimen Weight: 6.6 g
Tumor Focality: Multifocal, ipsilateral

----- DOMINANT TUMOR -----

Tumor Laterality: Right lobe
Tumor Size: Greatest dimension: 1.4cm
Additional dimension: 1.0 cm
Additional dimension: 0.9 cm
Histologic Type: Papillary carcinoma, classical (usual)
Papillary carcinoma, follicular variant
Classical (papillary) architecture
Follicular architecture
Classical cytomorphology
Histologic Grade: Not applicable

ICD-O-3

carcinoma, papillary, thyroid
8260/3

Site: thyroid, NOS C73.9

8/24/11

[page 2 of 2]
Margins:	Margins uninvolved by carcinoma Distance of invasive carcinoma to closest margin: 0.21mm
Tumor Capsule:	Partially encapsulated
Tumor Capsular Invasion:	Present, extent minimal
Lymph-Vascular Invasion:	Not identified
Perineural Invasion:	Not identified
Extrathyroidal Extension:	Not identified

----- SECOND TUMOR ----

Tumor Laterality:	Right lobe
Tumor Size:	Greatest dimension: 0.4cm
Histologic Type:	Papillary carcinoma, follicular variant Follicular architecture Classical cytomorphology
Histologic Grade:	Not applicable
Margins:	Margins uninvolved by carcinoma
Tumor Capsule:	Partially encapsulated
Tumor Capsular Invasion:	Present, extent minimal
Lymph-Vascular Invasion:	Not identified
Perineural Invasion:	Not identified
Extrathyroidal Extension:	Not identified
TNM Descriptors:	m (multiple primary tumors)
Primary Tumor (pT):	pT1b: Tumor more than 1 cm but not more than 2 cm in greatest dimension, limited to the thyroid
Regional Lymph Nodes (pN):	pNX: Regional lymph nodes cannot be assigned Number of regional lymph nodes examined: 0 Number of regional lymph nodes involved: 0
Distant Metastasis (pM):	Not applicable
Additional Pathologic Findings:	Adenomatoid nodule(s) or Nodular follicular disease Thyroiditis, focal (nonspecific)

*Pathologic Staging is based on AJCC/UICC TNM, 7th Edition

Electronically

verified by:

Gross Description

The specimen labeled with the patient's name and as "right hemithyroid lobe-stitch marks superior pole" consists of a right hemithyroidectomy specimen that is oriented with a suture and weighs 6.6 g (fresh). The lobe measures 4.1 cm SI x 2.0 cm ML x 1.3 cm AP and the isthmus measures 1.9 SI x 0.2 cm ML x 0.3 cm AP. The external surfaces have fibrous adhesions. No parathyroid glands and/or lymph nodes are identified grossly. The external surface is painted with Silver nitrate. The right superior lobe contains a well delineated nodule that measures 1.4 cm SI x 1.0 cm ML x 0.9 cm AP. A smaller nodule measuring 0.6 cm SI x 0.2 cm in ML x 0.2 cm AP is also identified. The remainder of the thyroid tissue is grossly unremarkable. Sections of nodule and normal tissue are stored frozen. The remainder of the specimen is submitted as follows:

1A- I lobe, superior to inferior
1J isthmus

Source: NCI Genomic Data Commons file 6699eafa-a156-4630-aa30-bf8b8e66b13d (TCGA-EM-A2P3.22142C95-F5AF-4C35-A12A-2B62321DFED7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).